Somatic mutation profile of tumor specimen TCGA-CD-A4MJ-01A (aliquot TCGA-CD-A4MJ-01A-11D-A25D-08) from TCGA case TCGA-CD-A4MJ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 60.0 years (21,932 days).
Specimen TCGA-CD-A4MJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0012809b-e4e6-466a-96f0-24311e4d4120.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-A4MJ-10A (Blood Derived Normal), aliquot TCGA-CD-A4MJ-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/320c536b-48ff-4b31-a6d3-b41251bd51e3

The open-access MAF lists 799 somatic variants for this specimen: 619 protein-altering or splice-affecting, 162 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 395, Silent 162, Frame Shift Del 150, Frame Shift Ins 35, Nonsense Mutation 18, Splice Site 12, Intron 8, RNA 7, In Frame Del 5, Splice Region 3, 5'Flank 2, In Frame Ins 1.

Variants (750 of 799; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.910del p.T304Qfs*23 | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- APC | c.3306C>G p.Y1102* | Nonsense Mutation (SNP) | VAF 6/126 reads (5%) | catalogued as rs879254092, CD005361, CM085240, CM920046; ClinVar: pathogenic; called by muse, mutect2
- ASS1 | c.412dup p.Q138Pfs*12 | Frame Shift Ins (INS) | VAF 19/69 reads (28%) | catalogued as rs1554983717; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CACNA1C | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); catalogued as rs1057517711, CM158505, COSV59732331; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- COL3A1 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912926, CM000314, CM1412408, CM970359, COSV58590697; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 84/256 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GRXCR1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 43/184 reads (23%) | catalogued as rs761349153, CM153971, COSV67670021; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNQ3 | c.1599del p.K533Nfs*6 | Frame Shift Del (DEL) | VAF 48/171 reads (28%) | catalogued as rs762289015, COSV101196388; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SERPING1 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281875170, BM1165483, CS053489, CS961498, COSV53542890; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AACS | c.1001G>A p.G334D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55537779; called by muse, mutect2, varscan2
- AAR2 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.524); catalogued as COSV57924148; called by muse, mutect2, varscan2
- ABCA9 | c.2798T>G p.L933R | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60626496; called by muse, mutect2, varscan2
- ACO2 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.566); catalogued as rs777420895, COSV53443452; called by muse, mutect2, varscan2
- ACSL5 | c.1408G>A p.A470T (on ENST00000354273; = p.A526T on NM_016234.3) | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV61129883; called by muse, mutect2, varscan2
- ACSM2B | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.546); catalogued as rs1222642876, COSV61658396; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 72/104 reads (69%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM30 | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 28/89 reads (31%) | catalogued as COSV65561369; called by muse, mutect2, varscan2
- ADAM8 | c.1548G>T p.Q516H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV101291764, COSV69864804; called by muse, mutect2, varscan2
- ADAMTS1 | c.1745C>T p.T582M | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs200821463, COSV53171170; called by muse, mutect2
- ADAMTS18 | c.3188A>G p.E1063G | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51417603; called by muse, mutect2, varscan2
- ADCYAP1 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs772983512, COSV99036150, COSV99327513; called by muse, mutect2, varscan2
- ADGRV1 | c.832A>G p.I278V | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1258586706, COSV67987797; called by muse, mutect2, varscan2
- AEBP1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV56258774; called by muse, mutect2, varscan2
- AHNAK | c.12712G>A p.A4238T | Missense Mutation (SNP) | VAF 94/356 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as COSV57217254; called by muse, mutect2, varscan2
- AIMP2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs770771902, COSV52240490; called by muse, mutect2, varscan2
- AL136295.1 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 11/295 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99841720; called by muse, mutect2
- ALG5 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.074); catalogued as rs767947559, COSV53504724; called by muse, mutect2, varscan2
- ALPK3 | c.1400C>T p.T467I | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV51934849; called by muse, mutect2, varscan2
- ANKMY1 | c.2151G>T p.Q717H | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV56036052; called by muse, mutect2, varscan2
- ANKRD34B | c.802C>T p.L268F | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV58614095; called by muse, mutect2, varscan2
- ANOS1 | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs372392838, COSV52920966; called by muse, mutect2, varscan2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 63/276 reads (23%) | catalogued as rs759218332; called by mutect2, varscan2
- APOB | c.8977G>A p.D2993N | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs1046539639, COSV51938081, COSV51941541; called by muse, mutect2, varscan2
- APPBP2 | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV50027325; called by muse, mutect2, varscan2
- AR | c.2440T>G p.F814V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101017553, COSV65954499; called by muse, mutect2, varscan2
- ARC | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV63078863; called by muse, mutect2, varscan2
- ARHGEF1 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs375950739; called by muse, mutect2, varscan2
- ARHGEF15 | c.1504G>T p.G502W | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62725557; called by muse, mutect2, varscan2
- ARID1A | c.6584T>C p.L2195P | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61380158; called by muse, mutect2, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs776520069; called by mutect2, varscan2
- ARMC5 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs549433680, COSV51657368; called by muse, mutect2, varscan2
- ARV1 | c.448+2T>C p.X150_splice | Splice Site (SNP) | VAF 52/181 reads (29%) | catalogued as COSV59618027; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASIC1 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57318516; called by muse, mutect2, varscan2
- ASPM | c.8432A>G p.Y2811C | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV54131999; called by muse, mutect2, varscan2
- ASXL2 | c.3067A>G p.T1023A | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV55460597; called by muse, mutect2, varscan2
- ATG9A | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs766008146, COSV60133586; called by muse, mutect2, varscan2
- AUTS2 | c.3454C>T p.R1152W | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769208197, COSV61410361; called by muse, mutect2, varscan2
- BCL9L | c.1346del p.P449Lfs*14 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs754310793, COSV52681762; called by mutect2, pindel, varscan2
- BHLHE22 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs1250934563, COSV58862038; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BSND | c.493C>A p.H165N | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV64870808; called by muse, mutect2, varscan2
- BUD13 | c.1712C>A p.P571H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52768683; called by muse, mutect2, varscan2
- C12orf56 | c.1616T>C p.V539A (on ENST00000543942 / NM_001170633.2; = p.V379A on NM_001099676.3) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV61487698; called by muse, mutect2, varscan2
- C3AR1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.106); catalogued as COSV50819799; called by muse, mutect2, varscan2
- CACHD1 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs762523710, COSV51554943; called by muse, mutect2, varscan2
- CACNA1D | c.3556C>T p.R1186W (on ENST00000350061 / NM_001128840.3; = p.R1206W on NM_000720.4) | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV55451901; called by muse, mutect2, varscan2
- CACTIN | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs757172712, COSV50269051; called by muse, mutect2
- CASKIN1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV58873534; called by muse, mutect2, varscan2
- CC2D1B | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.241); catalogued as COSV99429964; called by muse, mutect2
- CCDC14 | c.2633C>T p.T878M (on ENST00000488653; = p.T830M on NM_022757.5) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763135281, COSV59945484; called by muse, mutect2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC24 | c.640_642del p.K214del | In Frame Del (DEL) | VAF 31/119 reads (26%) | catalogued as rs764735746; called by pindel, varscan2
- CCDC69 | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62599942; called by muse, mutect2, varscan2
- CDC40 | c.870C>T p.G290= | Splice Region (SNP) | VAF 50/160 reads (31%) | catalogued as rs559751620, COSV57010223; called by muse, mutect2, varscan2
- CDC73 | c.1325T>G p.V442G | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66467734; called by muse, mutect2, varscan2
- CDHR3 | c.2644C>T p.H882Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1326346871, COSV58418447; called by muse, mutect2, varscan2
- CDX1 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.057); catalogued as COSV51568604; called by muse, mutect2
- CELF2 | c.190G>A p.G64R (on ENST00000416382 / NM_001025077.3; = p.G71R on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202642426, COSV100256705, COSV59973961; called by muse, mutect2, varscan2
- CHD4 | c.3275G>A p.R1092Q (on ENST00000357008 / NM_001363606.2; = p.R1105Q on NM_001273.5) | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100537532, COSV100537818, COSV58899203; called by muse, mutect2, varscan2
- CHD9 | c.1517G>T p.R506M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV68298616; called by muse, mutect2, varscan2
- CHIA | c.1106G>A p.G369D (on ENST00000343320; = p.G261D on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV58476003; called by muse, mutect2, varscan2
- CHRNB4 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs375172518; called by muse, mutect2, varscan2
- CKB | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs1448275362, COSV62379556; called by muse, mutect2, varscan2
- CKMT1A | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs759998899, COSV63256959; called by muse, mutect2, varscan2
- COBL | c.121dup p.H41Pfs*31 | Frame Shift Ins (INS) | VAF 28/74 reads (38%) | catalogued as rs778516787; called by mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 32/109 reads (29%) | catalogued as rs748995811; called by mutect2, varscan2
- COL16A1 | c.4603G>A p.G1535S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54708166, COSV99595160; called by muse, mutect2, varscan2
- COL9A1 | c.848del p.P283Lfs*45 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as rs941174282; called by pindel, varscan2
- COL9A1 | c.842G>C p.G281A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs745369282, COSV57878243, COSV57881698; called by muse, varscan2
- CPNE5 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs938648583, COSV55197391; called by muse, mutect2, varscan2
- CREBBP | c.6661A>G p.M2221V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as CM021087, COSV52127760; called by muse, mutect2, varscan2
- CRIM1 | c.2649T>G p.N883K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV54866356; called by muse, mutect2, varscan2
- CROCC | c.2222T>G p.L741R | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV100978212; called by muse, mutect2, varscan2
- CRY1 | c.935A>C p.N312T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50484227; called by muse, mutect2, varscan2
- CRY2 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs200945082, COSV69888718; called by muse, mutect2, varscan2
- CRYBG3 | c.5930C>T p.T1977I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV51712787; called by muse, mutect2, varscan2
- CRYZL1 | c.488A>G p.Q163R | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51678140; called by muse, mutect2, varscan2
- CTCFL | c.754+1G>A p.X252_splice | Splice Site (SNP) | VAF 24/88 reads (27%) | catalogued as COSV54775577; called by muse, mutect2, varscan2
- CYFIP2 | c.3469G>A p.A1157T (on ENST00000616178 / NM_001291722.2; = p.A1132T on NM_014376.4) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs369611074; called by muse, mutect2, varscan2
- CYREN | c.467del p.F156Sfs*5 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | catalogued as rs1402345687; called by mutect2, pindel, varscan2
- CYTH4 | c.805C>A p.L269I | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.105); catalogued as COSV50633241; called by muse, mutect2, varscan2
- DACT1 | c.1241C>A p.S414Y | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV60021438; called by muse, mutect2, varscan2
- DAGLA | c.2256G>T p.Q752H | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); catalogued as COSV57197196; called by muse, mutect2
- DAW1 | c.1127C>T p.T376I | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV59366320; called by muse, mutect2, varscan2
- DCAF13 | c.1220A>C p.Q407P | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.334); catalogued as COSV52572588; called by muse, mutect2, varscan2
- DCDC2 | c.759+2T>C p.X253_splice | Splice Site (SNP) | VAF 28/71 reads (39%) | catalogued as COSV65832476; called by muse, mutect2, varscan2
- DCHS1 | c.6706G>T p.D2236Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55037566; called by muse, mutect2, varscan2
- DDN | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV60293167; called by muse, mutect2, varscan2
- DGCR8 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.392); catalogued as COSV61227206; called by muse, mutect2, varscan2
- DHX35 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs372370618; called by muse, mutect2, varscan2
- DHX37 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs765933453, COSV58135659; called by muse, mutect2, varscan2
- DIDO1 | c.1425del p.E476Rfs*4 | Frame Shift Del (DEL) | VAF 58/152 reads (38%) | catalogued as rs762377755; called by mutect2, varscan2
- DIP2A | c.4195G>A p.G1399R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs747845913, COSV59479683; called by muse, mutect2, varscan2
- DISP1 | c.3007A>C p.T1003P | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52660601; called by muse, mutect2, varscan2
- DISP2 | c.1731dup p.L578Afs*214 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | catalogued as rs745509399; called by mutect2, varscan2
- DKK2 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1224653488, COSV53398183, COSV53400723; called by muse, mutect2, varscan2
- DLL4 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs771130564, COSV51063853; called by muse, mutect2, varscan2
- DNAAF1 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57577712; called by muse, mutect2
- DNAH1 | c.10341A>G p.I3447M | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV70230383; called by muse, mutect2, varscan2
- DNAH3 | c.3379G>T p.A1127S | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV54529031, COSV54542538; called by muse, mutect2, varscan2
- DNAH5 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs747116308, COSV54232720; called by muse, mutect2, varscan2
- DNAH8 | c.3141G>T p.Q1047H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV59455240; called by muse, mutect2, varscan2
- DNAH8 | c.13270G>A p.V4424I | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.525); catalogued as COSV59455265; called by muse, mutect2
- DNAI3 | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs1236694670, COSV54003498, COSV99641981; called by muse, mutect2, varscan2
- DOCK10 | c.2263C>T p.H755Y | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV51418004; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DTX2 | c.1001C>A p.A334E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV56861703; called by muse, mutect2, varscan2
- DYTN | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs184242013, COSV71752308; called by muse, mutect2, varscan2
- EBF2 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs1176695970, COSV101282277, COSV68777405; called by muse, mutect2, varscan2
- EFEMP2 | c.1220del p.G407Afs*14 | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | catalogued as COSV100337415; called by mutect2, pindel, varscan2
- EFNB3 | c.836del p.G279Vfs*15 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs1241382696; called by mutect2, pindel
- EGF | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs373552129; called by muse, mutect2, varscan2
- EGR2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 58/229 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV54346491; called by muse, mutect2, varscan2
- EGR2 | c.824del p.G275Afs*6 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as COSV99653876; called by pindel, varscan2
- EIF4A2 | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV56217381; called by muse, mutect2, varscan2
- EMD | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as COSV63962252; called by muse, mutect2, varscan2
- EMP2 | c.299T>C p.I100T | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV63996083; called by muse, mutect2, varscan2
- ENOSF1 | c.896C>G p.A299G (on ENST00000340116 / NM_001354066.2; = p.A251G on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51893356; called by muse, mutect2, varscan2
- ENTPD4 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.953); catalogued as COSV62269347; called by muse, mutect2, varscan2
- ERF | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55896428, COSV55897033; called by muse, mutect2, varscan2
- ESR2 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs368924653; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 56/130 reads (43%) | catalogued as rs775950025; called by mutect2, varscan2
- EYS | c.1520G>A p.C507Y | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.166); catalogued as COSV60986007, COSV60989197; called by muse, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM107B | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 103/303 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV51679373; called by muse, mutect2, varscan2
- FAM133A | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.88); catalogued as COSV59075664, COSV59076133; called by muse, mutect2, varscan2
- FAM160B1 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.929); catalogued as COSV65086618; called by muse, mutect2, varscan2
- FAM160B2 | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as rs756579712, COSV57157966; called by muse, mutect2, varscan2
- FAT3 | c.13544C>T p.S4515L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs768827430, COSV53126641; called by muse, mutect2, varscan2
- FAT4 | c.4934G>A p.G1645D | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67889691; called by muse, mutect2, varscan2
- FBXO15 | c.685T>C p.Y229H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV54046290; called by muse, mutect2, varscan2
- FBXO38 | c.1094-1G>T p.X365_splice | Splice Site (SNP) | VAF 37/108 reads (34%) | catalogued as COSV57028740; called by muse, mutect2, varscan2
- FCGR2B | c.251G>T p.W84L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52681986; called by muse, mutect2, varscan2
- FCN1 | c.184C>G p.P62A | Missense Mutation (SNP) | VAF 116/358 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV65662552; called by muse, mutect2, varscan2
- FER | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 34/113 reads (30%) | catalogued as COSV55294427; called by muse, mutect2, varscan2
- FKTN | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV56310192; called by muse, mutect2, varscan2
- FMO1 | c.1021T>C p.S341P | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.134); catalogued as COSV61446269; called by muse, mutect2, varscan2
- FOXO4 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766209807, COSV58575550; called by muse, mutect2, varscan2
- GABRR3 | c.331A>G p.R111G | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV72084153; called by muse, mutect2, varscan2
- GASK1B | c.755del p.G252Afs*23 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | catalogued as rs762957217; called by mutect2, pindel, varscan2
- GLI3 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs750890677, COSV67889940; called by muse, mutect2, varscan2
- GMIP | c.1849C>A p.H617N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99179261; called by muse, mutect2
- GNG13 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200381353, COSV50210270; called by muse, mutect2, varscan2
- GOLGA3 | c.2444A>G p.E815G | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV52634370; called by muse, mutect2, varscan2
- GPR152 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as COSV56886920; called by muse, mutect2, varscan2
- GPR37 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV58257504; called by muse, mutect2, varscan2
- GPR52 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52302890; called by muse, mutect2
- GPR82 | c.142dup p.T48Nfs*88 | Frame Shift Ins (INS) | VAF 20/30 reads (67%) | catalogued as rs765876009; called by mutect2, varscan2
- GPR83 | c.747C>G p.I249M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.049); catalogued as COSV54719101, COSV99703522; called by muse, mutect2, varscan2
- GRID1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751158483, COSV60025468; called by muse, mutect2, varscan2
- GRM5 | c.2480C>A p.A827D | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV59610612; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2264C>A p.P755H (on ENST00000265755 / NM_016328.3; = p.P740H on NM_005685.4) | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99734680; called by muse, mutect2
- GTPBP1 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53285664; called by muse, mutect2, varscan2
- HAPLN4 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV99363780; called by muse, mutect2
- HCAR1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV63675089; called by muse, mutect2
- HDGFL3 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); catalogued as COSV55206557; called by muse, mutect2
- HECA | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.617); catalogued as rs766148085, COSV62768641; called by muse, mutect2, varscan2
- HK2 | c.686T>C p.I229T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51876266; called by muse, mutect2, varscan2
- HLA-B | c.797A>G p.Q266R | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV69521648; called by muse, mutect2, varscan2
- HMCN1 | c.3875-1G>A p.X1292_splice | Splice Site (SNP) | VAF 8/67 reads (12%) | catalogued as COSV54909514; called by muse, mutect2
- HNRNPM | c.470T>C p.M157T | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV57693101; called by muse, mutect2
- HOXD8 | c.329del p.P110Lfs*67 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as rs770632206; called by mutect2, varscan2
- HRH2 | c.1042A>G p.T348A | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV51574779; called by muse, mutect2
- HS3ST2 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1029443879, COSV54463649; called by muse, mutect2, varscan2
- HSPB6 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99137435; called by muse, mutect2, varscan2
- HSPBP1 | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV55334462; called by muse, mutect2, varscan2
- HTR4 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); catalogued as rs201201172; called by muse, mutect2, varscan2
- HYOU1 | c.1910del p.P637Hfs*60 | Frame Shift Del (DEL) | VAF 23/81 reads (28%) | catalogued as COSV101345529; called by mutect2, pindel, varscan2
- ICA1L | c.111del p.E38Rfs*30 | Frame Shift Del (DEL) | VAF 38/139 reads (27%) | catalogued as rs1330717036; called by mutect2, pindel, varscan2
- ICE2 | c.244A>C p.I82L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs753709361, COSV55031900; called by muse, mutect2, varscan2
- IFT81 | c.1092G>T p.E364D | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV54363550; called by muse, mutect2
- IGHM | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as rs375873260; called by muse, mutect2
- IL31 | c.221G>T p.S74I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV65476283, COSV65476410; called by muse, mutect2, varscan2
- ILF3 | c.2015A>G p.Y672C | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV51559063; called by muse, mutect2, varscan2
- INO80E | c.42del p.K14Nfs*5 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | catalogued as rs762875806; called by mutect2, varscan2
- IP6K1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.271); catalogued as rs745434505, COSV58664028; called by muse, varscan2
- IPO9 | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.085); catalogued as rs373531363, COSV64234097; called by muse, mutect2, varscan2
- IQCN | c.703del p.L235Wfs*17 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | catalogued as rs748291022, COSV66574173; called by mutect2, pindel, varscan2
- IQUB | c.1403dup p.L468Ffs*3 | Frame Shift Ins (INS) | VAF 9/49 reads (18%) | catalogued as rs1386200642; called by mutect2, pindel, varscan2
- ITPRIPL2 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV67347324, COSV67347766; called by muse, mutect2, varscan2
- KANK1 | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV63213013; called by muse, mutect2
- KASH5 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763826408, COSV71358073; called by muse, mutect2, varscan2
- KATNIP | c.4558G>A p.V1520M | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55183409; called by muse, mutect2, varscan2
- KCNC1 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56391621; called by muse, mutect2, varscan2
- KCNF1 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920977, COSV54462507, COSV99705524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 20/81 reads (25%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KCTD19 | c.2301del p.V768Wfs*38 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | catalogued as rs759860142; called by mutect2, pindel, varscan2
- KCTD8 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.379); catalogued as rs868320335, COSV63590671; called by muse, mutect2, varscan2
- KDM3B | c.3188G>A p.R1063Q | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as rs758977082, COSV58691835; called by muse, mutect2, varscan2
- KIAA1109 | c.9082C>T p.R3028C | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1173813709, COSV52678142; called by muse, mutect2, varscan2
- KIF16B | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs1045068812, COSV61701872; called by muse, mutect2, varscan2
- KIF20B | c.3999A>T p.E1333D (on ENST00000371728 / NM_001284259.2; = p.E1293D on NM_016195.4) | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV53309433; called by muse, mutect2
- KIFAP3 | c.607del p.C203Vfs*22 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs1380692252; called by mutect2, pindel, varscan2
- KLHL18 | c.1717A>G p.T573A | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV51746443; called by muse, mutect2, varscan2
- KMO | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63809012; called by muse, mutect2, varscan2
- KMT2C | c.13822C>T p.R4608C | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as rs764910946, COSV51423935; called by muse, mutect2, varscan2
- KRT83 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53340802; called by muse, mutect2, varscan2
- L1CAM | c.3227C>T p.T1076M | Missense Mutation (SNP) | VAF 93/145 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.172); catalogued as rs781826722, COSV62828592; called by muse, mutect2, varscan2
- LACTB2 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 77/365 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs369180364; called by muse, mutect2, varscan2
- LAMA3 | c.3880C>T p.R1294W | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs758622204, COSV58071274; called by muse, mutect2, varscan2
- LAMC1 | c.3239G>T p.R1080M | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV51147927; called by muse, mutect2, varscan2
- LAPTM5 | c.691C>A p.L231I | Missense Mutation (SNP) | VAF 30/281 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.116); catalogued as COSV53853591; called by muse, mutect2, varscan2
- LARGE2 | c.1592A>G p.Y531C | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV57655531; called by muse, mutect2, varscan2
- LATS1 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.717); catalogued as rs147658805; called by muse, mutect2, varscan2
- LCT | c.3320C>T p.T1107M | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs937987859, COSV51551568, COSV51559414; called by muse, mutect2, varscan2
- LGI3 | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757547343, COSV60443691; called by muse, mutect2, varscan2
- LIAS | c.107del p.K36Rfs*31 | Frame Shift Del (DEL) | VAF 46/170 reads (27%) | catalogued as rs748571616; called by mutect2, varscan2
- LIAS | c.445C>T p.R149W (on ENST00000261434 / NM_001363700.2; = p.R252W on NM_006859.4) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775053206, COSV54695847; called by muse, mutect2, varscan2
- LMX1A | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.076); catalogued as COSV99671926; called by muse, mutect2, varscan2
- LOXL4 | c.403del p.R135Gfs*40 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as COSV53257058, COSV99583837; called by mutect2, pindel, varscan2
- LRBA | c.4112C>A p.A1371D | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV63957351; called by muse, mutect2, varscan2
- LRIG1 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs548930200, COSV56241890; called by muse, mutect2, varscan2
- LRIG1 | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56241908; called by muse, mutect2, varscan2
- LRP12 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs748604344, COSV52628819; called by muse, mutect2, varscan2
- LRP1B | c.10703C>A p.A3568E | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV67198999; called by muse, mutect2, varscan2
- LRRC7 | c.2042A>G p.H681R (on ENST00000651989 / NM_001370785.2; = p.H648R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV50432358; called by muse, mutect2
- LRRC8B | c.2204dup p.N735Kfs*2 | Frame Shift Ins (INS) | VAF 30/135 reads (22%) | catalogued as rs766512703; called by mutect2, pindel, varscan2
- LTBP3 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.978); catalogued as rs746544643, COSV100099610; called by mutect2, varscan2
- LYNX1-SLURP2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as rs770280004, COSV58186957; called by muse, mutect2, varscan2
- MACF1 | c.21326C>T p.A7109V (on ENST00000372915; = p.A5154V on NM_012090.5) | Missense Mutation (SNP) | VAF 40/148 reads (27%) | catalogued as rs1306583613, COSV57123524; called by muse, mutect2, varscan2
- MADD | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 125/371 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1388649838, COSV60625411; called by muse, mutect2, varscan2
- MAGEC3 | c.916T>A p.S306T | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV68923803; called by muse, mutect2, varscan2
- MAML3 | c.1956_1958dup p.P654dup | In Frame Ins (INS) | VAF 7/47 reads (15%) | catalogued as rs777873701; called by pindel, varscan2
- MAP2K3 | c.242T>C p.V81A (on ENST00000342679 / NM_145109.3; = p.V52A on NM_002756.4) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV57569635; called by muse, varscan2
- MAP7D3 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs765772763, COSV60171342; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MARCHF6 | c.1833A>G p.I611M | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as COSV56882769; called by muse, mutect2
- MARK4 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs928807888, COSV53464557; called by muse, mutect2, varscan2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs1203662025; called by mutect2, pindel, varscan2
- MBD1 | c.392+2T>C p.X131_splice | Splice Site (SNP) | VAF 51/230 reads (22%) | catalogued as COSV54003021; called by muse, mutect2, varscan2
- MBTD1 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs777875400, COSV64503639; called by muse, mutect2, varscan2
- MBTPS2 | c.792C>A p.D264E | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.527); catalogued as COSV63411798; called by muse, mutect2, varscan2
- MEI1 | c.1075del p.S359Pfs*13 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | catalogued as rs1280411643; called by mutect2, pindel, varscan2
- MEP1B | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52498076; called by muse, mutect2, varscan2
- MFSD2A | c.1081C>T p.Q361* (on ENST00000372809 / NM_001136493.3; = p.Q348* on NM_032793.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/141 reads (11%) | catalogued as COSV65685864; called by muse, mutect2, varscan2
- MGST2 | c.309del p.K103Nfs*8 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as COSV55498546; called by mutect2, pindel, varscan2
- MINAR1 | c.1144T>C p.S382P | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.1); catalogued as COSV59583857; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 37/128 reads (29%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MKI67 | c.9016G>A p.V3006I | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs756109830, COSV64075041; called by muse, mutect2, varscan2
- MMP17 | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs779153151, COSV62179778; called by muse, mutect2, varscan2
- MRC1 | c.3249C>T p.S1083= | Splice Region (SNP) | VAF 28/108 reads (26%) | catalogued as rs985728110; called by muse, varscan2
- MRGPRD | c.857G>T p.R286M | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.901); catalogued as COSV58423393; called by muse, mutect2, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/126 reads (27%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MRPL4 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV53448730; called by muse, mutect2, varscan2
- MRPS9 | c.762del p.K254Nfs*3 | Frame Shift Del (DEL) | VAF 22/89 reads (25%) | catalogued as rs1297979087; called by mutect2, pindel, varscan2
- MS4A15 | c.439G>A p.V147I (on ENST00000405633 / NM_001098835.2; = p.V54I on NM_152717.3) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs764559217, COSV61961369; called by muse, mutect2, varscan2
- MSR1 | c.843del p.G282Efs*18 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | catalogued as rs1197417676; called by mutect2, pindel, varscan2
- MTOR | c.1378C>T p.R460* | Nonsense Mutation (SNP) | VAF 35/107 reads (33%) | catalogued as COSV63873085; called by muse, mutect2, varscan2
- MUC16 | c.41597C>A p.P13866H | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.995); catalogued as COSV66693378; called by muse, mutect2, varscan2
- MUC16 | c.17684A>G p.Q5895R | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.019); catalogued as COSV67473997; called by muse, mutect2, varscan2
- MYH3 | c.5728C>T p.R1910C | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56866330; called by muse, mutect2, varscan2
- MYH4 | c.5802A>T p.K1934N | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV55120141; called by muse, mutect2, varscan2
- MYH6 | c.5075C>T p.A1692V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.375); catalogued as COSV62451838; called by muse, mutect2, varscan2
- MYL9 | c.434A>G p.E145G | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV54072599; called by muse, mutect2, varscan2
- MYO1D | c.1759G>A p.V587I | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.591); catalogued as rs143604215; called by muse, mutect2, varscan2
- MYO5A | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV62561329; called by muse, mutect2, varscan2
- MYO6 | c.2392T>C p.W798R | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64119515; called by muse, mutect2, varscan2
- MYORG | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs556518887, COSV52627510; called by muse, mutect2
- NAA11 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54514136, COSV54514397; called by muse, mutect2
- NAB2 | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV55666686; called by muse, mutect2, varscan2
- NCKAP1L | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.969); catalogued as COSV53208189; called by muse, mutect2, varscan2
- NCOA2 | c.4355T>G p.M1452R | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.263); catalogued as COSV51220284; called by muse, mutect2
- NEB | c.10721G>A p.S3574N | Missense Mutation (SNP) | VAF 107/361 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.363); catalogued as rs776337697, COSV51426871; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEDD4 | c.3715dup p.R1239Kfs*21 (on ENST00000508342 / NM_001284338.1; = p.R820Kfs*21 on NM_006154.4) | Frame Shift Ins (INS) | VAF 34/126 reads (27%) | catalogued as rs1452682012; called by mutect2, pindel, varscan2
- NELL2 | c.968A>G p.D323G | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.419); catalogued as rs757940415, COSV61577341; called by muse, mutect2, varscan2
- NFAM1 | c.241A>G p.S81G | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV61195327; called by muse, mutect2, varscan2
- NIBAN3 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.36); catalogued as COSV56310340; called by muse, mutect2
- NID2 | c.2017T>C p.S673P | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.723); catalogued as COSV53497947; called by muse, mutect2, varscan2
- NIN | c.2941C>T p.Q981* | Nonsense Mutation (SNP) | VAF 96/280 reads (34%) | catalogued as COSV55394839; called by muse, mutect2, varscan2
- NISCH | c.1016T>C p.L339P | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61900695; called by muse, mutect2, varscan2
- NKAPD1 | c.817_820del p.K273Afs*6 (on ENST00000280352 / NM_001082970.2; = p.K274Afs*6 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs780476786; called by pindel, varscan2
- NKTR | c.2297del p.N766Ifs*30 | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | catalogued as rs767007251; called by mutect2, varscan2
- NLRP2 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54756444; called by muse, mutect2, varscan2
- NOC4L | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as rs752337906, COSV57958657; called by muse, mutect2, varscan2
- NPAP1 | c.1553C>A p.S518Y | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV61506873; called by muse, mutect2, varscan2
- NPTX2 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.98); PolyPhen benign (0.015); catalogued as COSV55717645; called by muse, mutect2, varscan2
- NRDC | c.3030G>A p.M1010I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as COSV61405507; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | catalogued as rs776154715; called by mutect2, varscan2
- NRXN1 | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.379); catalogued as COSV68004078; called by muse, mutect2, varscan2
- NTSR1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); catalogued as rs769550075, COSV65138444; called by mutect2, varscan2
- OR2AK2 | c.569A>C p.Q190P | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.88); catalogued as COSV63554785; called by muse, mutect2, varscan2
- OR4D5 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs746149575, COSV58306026; called by muse, mutect2, varscan2
- OR51B5 | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56176362; called by muse, mutect2, varscan2
- OR52B2 | c.898C>A p.Q300K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV73209433; called by muse, mutect2, varscan2
- OR56B4 | c.631G>T p.V211F | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs779511351, COSV57204826; called by muse, mutect2, varscan2
- OR5A2 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV57391293; called by muse, mutect2, varscan2
- OR6Y1 | c.711G>T p.Q237H | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV56929837; called by muse, mutect2, varscan2
- OR7E24 | c.504del p.F168Lfs*12 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs1031417078; called by mutect2, pindel, varscan2
- OR8B2 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs141277809; called by muse, mutect2, varscan2
- ORC1 | c.-1C>A | Splice Region (SNP) | VAF 18/43 reads (42%) | catalogued as COSV99933292; called by muse, mutect2, varscan2
- OTOF | c.5405C>A p.A1802E (on ENST00000272371 / NM_194248.3; = p.A1035E on NM_004802.4) | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55506398; called by muse, mutect2, varscan2
- P4HA3 | c.689T>C p.L230S | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59042346; called by muse, mutect2, varscan2
- PAH | c.556A>C p.T186P | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD130699, COSV61017450; called by muse, mutect2, varscan2
- PAX2 | c.1216G>A p.A406T (on ENST00000428433 / NM_003987.5; = p.A383T on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/188 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV62291566; called by muse, mutect2, varscan2
- PAX4 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV58389420; called by muse, mutect2
- PCDHB5 | c.2328G>T p.Q776H | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); catalogued as COSV50647154, COSV50647363; called by muse, mutect2, varscan2
- PCDHGA2 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.005); catalogued as rs753861698, COSV66938679, COSV66940847; called by muse, mutect2, varscan2
- PCDHGB2 | c.1253A>G p.Y418C | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373182240, COSV53968062; called by muse, mutect2, varscan2
- PCDHGC5 | c.232A>C p.S78R | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV52755197; called by muse, mutect2, varscan2
- PDLIM7 | c.551A>C p.E184A | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV62883410; called by muse, mutect2, varscan2
- PDZD4 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51247604; called by muse, mutect2, varscan2
- PDZRN3 | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.047); catalogued as rs139110477, COSV99732075; called by muse, mutect2, varscan2
- PGAM2 | c.757A>G p.K253E | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV51978606; called by muse, mutect2, varscan2
- PGAP6 | c.782C>G p.A261G | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV51740282; called by muse, mutect2
- PGAP6 | c.221del p.P74Qfs*60 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs1287775735; called by mutect2, varscan2
- PGBD1 | c.2078G>A p.G693D | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1181275574, COSV52554026; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs769717544; called by mutect2, varscan2
- PHKA1 | c.3541G>A p.A1181T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs140865522, COSV59801883; called by muse, mutect2, varscan2
- PIGQ | c.1612C>T p.R538C (on ENST00000026218 / NM_148920.3; = p.G558= on NM_004204.5) | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs760639555, COSV50315164; ClinVar: likely benign; called by muse, mutect2, varscan2
- PIKFYVE | c.5810T>C p.M1937T | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52243227; called by muse, mutect2, varscan2
- PIM1 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 39/129 reads (30%) | catalogued as COSV65165948; called by muse, mutect2, varscan2
- PITPNA | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs747074455, COSV57932487; called by muse, mutect2, varscan2
- PLA2G15 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV54723520; called by muse, mutect2, varscan2
- PLAAT4 | c.483dup p.A162Sfs*55 | Frame Shift Ins (INS) | VAF 28/168 reads (17%) | catalogued as rs745860467; called by mutect2, varscan2
- PLAUR | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.173); catalogued as rs757884538, COSV55390293; called by muse, mutect2, varscan2
- PLCD3 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs747519089, COSV59561104; called by mutect2, varscan2
- PLCG1 | c.3092G>A p.C1031Y | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV54819748; called by muse, mutect2, varscan2
- PLEC | c.11260C>T p.R3754C (on ENST00000322810 / NM_201380.4; = p.R3644C on NM_000445.5) | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781877026, COSV59636573; called by muse, mutect2, varscan2
- PLEKHA5 | c.1921C>T p.R641* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV54703306; called by muse, mutect2, varscan2
- PLEKHF1 | c.491C>T p.T164M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV71410163; called by muse, mutect2
- PLEKHG1 | c.3094+2T>C p.X1032_splice | Splice Site (SNP) | VAF 35/89 reads (39%) | catalogued as COSV62048290; called by muse, mutect2, varscan2
- PLVAP | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs761581948, COSV53083196; called by muse, mutect2, varscan2
- PNN | c.1433C>A p.P478H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.421); catalogued as COSV53767026; called by muse, mutect2, varscan2
- PNPLA6 | c.1595A>G p.H532R (on ENST00000414982 / NM_001166111.2; = p.H484R on NM_006702.5) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV55379832; called by muse, mutect2, varscan2
- POLE | c.2539C>T p.R847W | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1428997822, COSV57678361; ClinVar: uncertain significance; called by muse, mutect2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 31/122 reads (25%) | catalogued as rs745933237; called by mutect2, pindel, varscan2
- POLR1A | c.2440C>T p.R814C | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs549375944, COSV55694632; called by muse, mutect2, varscan2
- PRDM13 | c.2012G>A p.G671D | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV65030063; called by muse, mutect2, varscan2
- PRDM14 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1308927556, COSV52573004; called by muse, mutect2, varscan2
- PRKD2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52187579; called by muse, mutect2, varscan2
- PRPF40B | c.99del p.M34Cfs*29 (on ENST00000380281; = p.M28Cfs*29 on NM_012272.3) | Frame Shift Del (DEL) | VAF 51/194 reads (26%) | catalogued as COSV56058435; called by mutect2, pindel, varscan2
- PRR35 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53463428; called by muse, mutect2
- PSMC5 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV56740051; called by muse, mutect2, varscan2
- PTOV1 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.848); catalogued as COSV55588617; called by muse, mutect2, varscan2
- PTP4A3 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 66/324 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as rs941573806, COSV61472132; called by muse, varscan2
- PTPA | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV61234485; called by muse, varscan2
- PTPN23 | c.3967G>A p.V1323I | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs778612238, COSV55545470, COSV55549752; called by muse, mutect2, varscan2
- PUDP | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66903087; called by muse, mutect2, varscan2
- RAB29 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.309); catalogued as COSV52521520; called by muse, mutect2, varscan2
- RAB33B | c.601A>G p.S201G | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV59777520; called by muse, mutect2, varscan2
- RABGAP1 | c.2789dup p.N930Kfs*7 | Frame Shift Ins (INS) | VAF 25/64 reads (39%) | catalogued as rs749213218; called by mutect2, varscan2
- RANBP3L | c.1210C>A p.H404N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56956240; called by muse, mutect2, varscan2
- RASGRF2 | c.3552+2T>C p.X1184_splice | Splice Site (SNP) | VAF 27/106 reads (25%) | catalogued as COSV54131938; called by muse, mutect2, varscan2
- RASGRP1 | c.2243A>G p.Y748C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV60365692; called by muse, mutect2, varscan2
- RASIP1 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.468); catalogued as COSV55805652; called by muse, mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBM48 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV50401533; called by muse, mutect2, varscan2
- RBM8A | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs868971393, COSV57162396; called by muse, mutect2, varscan2
- RCN3 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs373868597, COSV54542478; called by muse, mutect2, varscan2
- RECQL | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs202110155, COSV69658591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REPIN1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68292483; called by muse, mutect2, varscan2
- RGL2 | c.608dup p.S204Qfs*3 | Frame Shift Ins (INS) | VAF 58/217 reads (27%) | catalogued as rs762949421; called by mutect2, varscan2
- RGL3 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs142089258, COSV100993124; called by muse, mutect2, varscan2
- RGS12 | c.1297_1299del p.E433del | In Frame Del (DEL) | VAF 7/71 reads (10%) | catalogued as rs1194911154; called by pindel, varscan2
- RIMBP2 | c.636T>A p.Y212* | Nonsense Mutation (SNP) | VAF 34/131 reads (26%) | catalogued as COSV55475762; called by muse, mutect2, varscan2
- RIMS2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.611); catalogued as COSV68485582; called by muse, mutect2
- RIN2 | c.869G>C p.R290P (on ENST00000255006 / NM_001242581.1; = p.R241P on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV54789712, COSV54791096; called by muse, mutect2, varscan2
- RNASET2 | c.397_399del p.K133del | In Frame Del (DEL) | VAF 24/128 reads (19%) | catalogued as rs781239107; called by pindel, varscan2
- RNF17 | c.4432A>G p.T1478A | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV55042593; called by muse, mutect2, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 43/132 reads (33%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs752898741; called by mutect2, varscan2
- ROM1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs754380899, COSV53883034; called by muse, mutect2, varscan2
- ROPN1L | c.304A>G p.K102E | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as COSV56874101; called by muse, mutect2, varscan2
- RPS6KC1 | c.3115C>T p.R1039* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as rs780526542, COSV65300439; called by muse, mutect2, varscan2
- RTEL1 | c.1678_1680del p.F560del | In Frame Del (DEL) | VAF 12/70 reads (17%) | catalogued as rs779176651; called by pindel, varscan2
- RUFY4 | c.1481G>T p.R494M | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV60246839, COSV60247994; called by muse, mutect2, varscan2
- RUNDC3B | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56694191; called by muse, mutect2, varscan2
- RUNX1T1 | c.1412C>T p.A471V (on ENST00000265814 / NM_001198628.1; = p.A444V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1462140811, COSV56138272; called by muse, mutect2, varscan2
- RYR3 | c.6670C>T p.R2224C | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1188037949, COSV63109442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SBK1 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV59397411; called by muse, mutect2, varscan2
- SCN4B | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs771504011, COSV61252579; called by muse, mutect2, varscan2
- SCN7A | c.3436A>G p.T1146A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV69272513; called by muse, mutect2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as rs763181092; called by mutect2, pindel, varscan2
- SEC14L2 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs751272847, COSV57241528; called by muse, mutect2, varscan2
- SEC14L5 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV52039258; called by muse, mutect2, varscan2
- SEC16A | c.5626T>C p.W1876R | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51530560; called by muse, mutect2, varscan2
- SEC61A1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV54577633; called by muse, mutect2, varscan2
- SEMA3D | c.1523A>C p.N508T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52396295; called by muse, mutect2, varscan2
- SEMA5A | c.2375C>T p.S792L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs2290734, COSV66796225; called by muse, mutect2, varscan2
- SEMA5A | c.1332G>T p.L444F | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV101227130, COSV66796236; called by muse, mutect2, varscan2
- SEMA6A | c.1582T>C p.S528P | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV56712232; called by muse, mutect2, varscan2
- SHANK2 | c.3352G>A p.A1118T | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV53600383; called by muse, mutect2, varscan2
- SHROOM4 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs782042090, COSV56791194; called by muse, mutect2, varscan2
- SIAH2 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as rs758857423, COSV57262093; called by muse, mutect2, varscan2
- SIPA1L2 | c.4487G>T p.R1496M | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53392541, COSV99479530; called by muse, mutect2, varscan2
- SKA2 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV57521974; called by muse, mutect2, varscan2
- SLC12A9 | c.305dup p.G103Rfs*26 | Frame Shift Ins (INS) | VAF 21/121 reads (17%) | catalogued as rs766637822; called by mutect2, pindel, varscan2
- SLC17A7 | c.1181T>C p.V394A | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs745637195, COSV55548233; called by muse, mutect2, varscan2
- SLC22A16 | c.205T>C p.W69R | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.067); catalogued as COSV57930999; called by muse, mutect2, varscan2
- SLC39A6 | c.1611G>T p.K537N | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV99309588; called by muse, mutect2
- SLC44A3 | c.1722del p.F574Lfs*4 (on ENST00000271227 / NM_001114106.3; = p.F526Lfs*4 on NM_152369.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 62/227 reads (27%) | catalogued as rs752543591, COSV54732637; called by mutect2, pindel, varscan2
- SLC45A4 | c.1382T>C p.M461T (on ENST00000517878 / NM_001286646.2; = p.M410T on NM_001080431.2) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV50142715; called by muse, mutect2, varscan2
- SLC49A3 | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV59140742; called by muse, mutect2, varscan2
- SLC7A13 | c.1391T>C p.L464P | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52535107; called by muse, mutect2
- SLC9A1 | c.1680G>C p.K560N | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV56054241; called by muse, mutect2, varscan2
- SLFN5 | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV55481708; called by muse, mutect2, varscan2
- SLTM | c.1058+2T>C p.X353_splice | Splice Site (SNP) | VAF 22/73 reads (30%) | catalogued as COSV51054994; called by muse, mutect2, varscan2
- SMAD6 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1410638809, COSV56593597; called by muse, mutect2, varscan2
- SMARCC1 | c.2857C>T p.R953* | Nonsense Mutation (SNP) | VAF 18/302 reads (6%) | catalogued as COSV54379396; called by muse, mutect2
- SMG1 | c.4535G>A p.C1512Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV67172340; called by muse, mutect2, varscan2
- SMG5 | c.1517C>T p.T506M | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs772301844, COSV62435948; called by muse, mutect2, varscan2
- SMOC2 | c.764C>T p.T255M (on ENST00000356284 / NM_001166412.2; = p.T266M on NM_022138.3) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs367887452, COSV62436469; called by muse, varscan2
- SNED1 | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60026041; called by muse, mutect2, varscan2
- SNRPC | c.243dup p.S82Qfs*104 | Frame Shift Ins (INS) | VAF 34/98 reads (35%) | catalogued as rs1472546666; called by mutect2, pindel, varscan2
- SNTB1 | c.689dup p.S231Vfs*31 | Frame Shift Ins (INS) | VAF 22/141 reads (16%) | catalogued as rs762352897; called by mutect2, pindel, varscan2
- SOGA3 | c.722del p.G241Afs*133 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as rs778091058, COSV100846885; called by mutect2, pindel, varscan2
- SPECC1 | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.619); catalogued as rs763091276, COSV54960001; called by muse, mutect2, varscan2
- SPECC1 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs764238558, COSV54960010; called by muse, mutect2, varscan2
- SPEN | c.5881G>A p.D1961N | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as rs745908478, COSV65363444; called by muse, mutect2, varscan2
- SPNS1 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs772584925, COSV57954801; called by muse, mutect2, varscan2
- SPTBN2 | c.3960G>T p.Q1320H | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59454268; called by muse, mutect2, varscan2
- SRRM4 | c.1498T>A p.S500T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57418759; called by muse, varscan2
- SSC4D | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs369525573; called by muse, mutect2, varscan2
- SSH1 | c.2422C>T p.Q808* | Nonsense Mutation (SNP) | VAF 36/103 reads (35%) | catalogued as COSV58457243; called by muse, mutect2, varscan2
- STAB1 | c.4508T>C p.I1503T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.079); catalogued as COSV58738137; called by muse, mutect2, varscan2
- SUGP1 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV55922214; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs747003550; called by mutect2, varscan2
- SUMO3 | c.303_304del p.H101Qfs*21 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs780717596; called by pindel, varscan2
- SYBU | c.319A>C p.S107R (on ENST00000276646 / NM_001099754.2; = p.S106R on NM_017786.6) | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.931); catalogued as COSV52619536; called by muse, mutect2, varscan2
- SYNE1 | c.5587C>T p.R1863W (on ENST00000367255 / NM_182961.4; = p.R1870W on NM_033071.3) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs769949513, COSV54992747; called by muse, mutect2, varscan2
- SYNE2 | c.20623A>G p.M6875V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59941123; called by muse, mutect2, varscan2
- SYNGR2 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs774750671, COSV56745639; called by muse, mutect2, varscan2
- SZT2 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs767336909, COSV65170871; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SZT2 | c.4169T>C p.I1390T (on ENST00000634258 / NM_001365999.1; = p.I1333T on NM_015284.4) | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.236); catalogued as rs1456220865, COSV65170874; called by muse, mutect2, varscan2
- TAF7L | c.1337dup p.N446Kfs*2 | Frame Shift Ins (INS) | VAF 64/104 reads (62%) | catalogued as rs780573926; called by mutect2, varscan2
- TAOK2 | c.3255G>A p.W1085* | Nonsense Mutation (SNP) | VAF 34/106 reads (32%) | catalogued as rs1401327054, COSV54230592; called by muse, mutect2, varscan2
- TBC1D22A | c.1304C>T p.T435I | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV61440730; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBX4 | c.1291G>A p.V431M | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs774437880, COSV53605881; called by muse, mutect2, varscan2
- TENM4 | c.3719A>G p.D1240G | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53638277; called by muse, mutect2, varscan2
- TET3 | c.3019G>A p.A1007T | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs754843346, COSV69643269, COSV69645136; called by muse, mutect2, varscan2
- THAP12 | c.1251A>C p.K417N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV52611112; called by muse, mutect2, varscan2
- THBS4 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.993); catalogued as COSV63469695; called by muse, mutect2, varscan2
- TIAM1 | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775775144, COSV54557258; called by muse, mutect2, varscan2
- TLL1 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs1175843502, COSV50293938; called by muse, mutect2, varscan2
- TLR3 | c.603del p.K201Nfs*2 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as COSV57170713; called by mutect2, pindel, varscan2
- TLX3 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV51540640; called by muse, mutect2, varscan2
- TM4SF19 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1236617103, COSV56556900; called by muse, mutect2
- TMC1 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as COSV52777730; called by muse, mutect2, varscan2
- TMEM131 | c.341T>C p.M114T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV51778372; called by muse, mutect2, varscan2
- TMEM79 | c.487dup p.R163Pfs*9 | Frame Shift Ins (INS) | VAF 16/64 reads (25%) | catalogued as rs780694092; called by mutect2, varscan2
- TMOD3 | c.282del p.I97Yfs*23 | Frame Shift Del (DEL) | VAF 32/90 reads (36%) | catalogued as rs759399045; called by mutect2, varscan2
- TNC | c.3634A>G p.T1212A | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV60786053; called by muse, mutect2, varscan2
- TNFRSF4 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.536); catalogued as rs377530517, COSV55419808; called by muse, varscan2
- TNFRSF4 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as COSV55419812; called by muse, varscan2
- TP73 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs746207826, COSV60702387; called by muse, mutect2, varscan2
- TRAF7 | c.1115T>C p.L372P | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV58215272; called by muse, mutect2, varscan2
- TRAK1 | c.1655G>A p.R552H (on ENST00000327628 / NM_001349247.2; = p.R494H on NM_014965.5) | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as rs149693845; called by muse, mutect2, varscan2
- TRAPPC11 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); catalogued as rs1291703230, COSV58217093; called by muse, mutect2, varscan2
- TRIM23 | c.275del p.N92Ifs*69 | Frame Shift Del (DEL) | VAF 33/109 reads (30%) | catalogued as rs1465925764, COSV51550889; called by mutect2, varscan2
- TRIM37 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs781030263, COSV51885167; called by muse, mutect2, varscan2
- TRIM8 | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 111/315 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV56660890; called by muse, mutect2, varscan2
- TRRAP | c.7812G>T p.E2604D (on ENST00000359863 / NM_001244580.1; = p.E2586D on NM_003496.3) | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV62846604; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 22/42 reads (52%) | catalogued as rs756650873; called by mutect2, varscan2
- TTN | c.103030A>G p.N34344D (on ENST00000591111; = p.N26920D on NM_003319.4) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | PolyPhen benign (0.003); catalogued as COSV60134776; called by muse, mutect2, varscan2
- UBXN6 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as rs765840168, COSV56679415; called by muse, mutect2, varscan2
- UGGT2 | c.3084T>A p.N1028K | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV65075713; called by muse, mutect2, varscan2
- UNG | c.489C>A p.H163Q (on ENST00000242576 / NM_080911.3; = p.H154Q on NM_003362.4) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376918741, COSV54357633; called by muse, mutect2, varscan2
- URI1 | c.1206A>T p.E402D | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV56350791; called by muse, mutect2, varscan2
- USP36 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776872958, COSV61752098; called by muse, mutect2, varscan2
- UTRN | c.10270+1G>A p.X3424_splice | Splice Site (SNP) | VAF 21/80 reads (26%) | catalogued as rs141700678, COSV62310957; called by muse, mutect2, varscan2
- VANGL1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.239); catalogued as COSV59620896; called by muse, mutect2, varscan2
- VPS18 | c.825del p.K276Sfs*12 | Frame Shift Del (DEL) | VAF 40/118 reads (34%) | catalogued as rs778441869; called by mutect2, pindel, varscan2
- VPS28 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs782009994, COSV52872397; called by muse, mutect2, varscan2
- VSIG1 | c.688+1G>A p.X230_splice | Splice Site (SNP) | VAF 8/206 reads (4%) | catalogued as rs1357354685, COSV54260054; called by muse, mutect2
- WDFY2 | c.1087C>T p.H363Y | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV53290539; called by muse, mutect2
- WDR90 | c.812C>A p.P271Q | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.123); catalogued as COSV53471260; called by muse, mutect2, varscan2
- WDTC1 | c.868dup p.E290Gfs*7 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | catalogued as rs747972901; called by mutect2, varscan2
- WNT16 | c.991A>G p.T331A (on ENST00000222462 / NM_057168.2; = p.T321A on NM_016087.2) | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55976250; called by muse, mutect2
- WSCD2 | c.992T>C p.M331T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.838); catalogued as COSV54584685; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 26/105 reads (25%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBBX | c.1822T>G p.L608V | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV56789138, COSV56792270; called by muse, mutect2, varscan2
- ZBED4 | c.3089T>C p.I1030T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV53466218; called by muse, mutect2, varscan2
- ZC3H10 | c.542T>C p.V181A | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57769326; called by muse, mutect2, varscan2
- ZC3H13 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 33/338 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as COSV54456398; called by muse, mutect2
- ZFAT | c.988T>C p.Y330H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs764782858, COSV100914398, COSV64740502; called by muse, mutect2, varscan2
- ZFHX4 | c.5821G>A p.E1941K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs544904221, COSV51441830; called by muse, mutect2, varscan2
- ZFP37 | c.482del p.N161Ifs*24 | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | catalogued as rs563751025; called by mutect2, varscan2
- ZHX2 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.152); catalogued as COSV58714190; called by muse, mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZNF207 | c.314A>G p.Q105R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV58300448, COSV58302045; called by muse, mutect2, varscan2
- ZNF283 | c.1976G>A p.C659Y | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV61031591; called by muse, mutect2, varscan2
- ZNF287 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as rs770221561, COSV67688069; called by muse, mutect2, varscan2
- ZNF311 | c.874A>G p.M292V | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1335931553, COSV65853167; called by muse, mutect2, varscan2
- ZNF330 | c.14del p.K5Rfs*18 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs770975379; called by mutect2, varscan2
- ZNF343 | c.1750C>T p.R584* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as rs751928345, COSV53854354; called by muse, mutect2, varscan2
- ZNF536 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs779917944, COSV62826369; called by muse, mutect2, varscan2
- ZNF562 | c.1070C>T p.T357M (on ENST00000453372 / NM_001130032.2; = p.T285M on NM_017656.4) | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs1202814504, COSV53333304; called by muse, mutect2, varscan2
- ZNF614 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as rs774860652, COSV54546289; called by muse, mutect2, varscan2
- ZNF699 | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV58026015; called by muse, mutect2, varscan2
- ZNF786 | c.1374T>G p.C458W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60276637; called by muse, mutect2
- ZNF8 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.548); catalogued as rs147485828; called by muse, mutect2, varscan2
- ZNF835 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.177); catalogued as rs767397626, COSV73379513; called by muse, mutect2, varscan2
- ZRANB2 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs144217678; called by muse, mutect2, varscan2
- ABCA13 | c.7157dup p.T2387Hfs*12 | Frame Shift Ins (INS) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- ACAD11 | c.1383del p.F461Lfs*46 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- AKAP12 | c.2844del p.T949Rfs*23 | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.2244del p.G749Vfs*12 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- APC | c.636del p.K212Nfs*7 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- ARHGAP35 | c.2834del p.K945Rfs*3 | Frame Shift Del (DEL) | VAF 43/143 reads (30%) | called by mutect2, pindel, varscan2
- ARHGEF5 | c.4540del p.Q1514Rfs*24 | Frame Shift Del (DEL) | VAF 61/248 reads (25%) | called by mutect2, pindel, varscan2
- ATG5 | c.704del p.K235Rfs*4 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- ATXN2L | c.2551del p.Q851Kfs*69 | Frame Shift Del (DEL) | VAF 63/260 reads (24%) | called by mutect2, pindel, varscan2
- B3GLCT | c.238del p.S80Afs*3 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, varscan2
- BBOF1 | c.70del p.T24Qfs*44 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- BMPR2 | c.1028del p.N343Mfs*14 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel
- C1R | c.689del p.P230Lfs*100 (on ENST00000536053 / NM_001354346.2; = p.P216Lfs*100 on NM_001733.7) | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- C3orf20 | c.229del p.L77Wfs*15 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- CACUL1 | c.321del p.T108Pfs*16 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- CAMK1G | c.310del p.E104Sfs*20 | Frame Shift Del (DEL) | VAF 48/212 reads (23%) | called by mutect2, pindel, varscan2
- CDH10 | c.1920del p.E641Sfs*3 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- CDH23 | c.10045del p.L3349Wfs*8 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- CENPC | c.406del p.I136Yfs*6 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- CITED2 | c.528del p.G177Afs*42 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel
- CLCA1 | c.428dup p.L144Vfs*3 | Frame Shift Ins (INS) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- COL13A1 | c.1623del p.E543Rfs*51 (on ENST00000398978 / NM_001130103.2; = p.E486Rfs*36 on NM_080798.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 32/169 reads (19%) | called by mutect2, pindel, varscan2
- DEFB127 | c.243dup p.Q82Sfs*34 | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- DNAH7 | c.8194del p.I2732Lfs*15 | Frame Shift Del (DEL) | VAF 26/83 reads (31%) | called by mutect2, varscan2
- DOK1 | c.675dup p.S226Lfs*15 | Frame Shift Ins (INS) | VAF 65/224 reads (29%) | called by mutect2, pindel, varscan2
- EPHB2 | c.985dup p.Q329Pfs*9 | Frame Shift Ins (INS) | VAF 26/103 reads (25%) | called by mutect2, pindel, varscan2
- FADD | c.456_457del p.K153Gfs*22 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by pindel, varscan2
- FCRL3 | c.952_953del p.V318Hfs*15 | Frame Shift Del (DEL) | VAF 34/144 reads (24%) | called by mutect2, pindel, varscan2
- FOXP2 | c.1790dup p.N597Kfs*13 | Frame Shift Ins (INS) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- GABRA2 | c.399del p.K133Nfs*3 | Frame Shift Del (DEL) | VAF 35/105 reads (33%) | called by mutect2, pindel, varscan2
- GGA3 | c.497del p.N166Tfs*13 (on ENST00000537686 / NM_138619.4; = p.N133Tfs*13 on NM_014001.5) | Frame Shift Del (DEL) | VAF 68/189 reads (36%) | called by mutect2, varscan2
- GMEB2 | c.250del p.E84Rfs*32 | Frame Shift Del (DEL) | VAF 30/117 reads (26%) | called by mutect2, pindel, varscan2
- GON4L | c.400del p.M134* | Frame Shift Del (DEL) | VAF 38/162 reads (23%) | called by mutect2, pindel, varscan2
- GPR179 | c.6955C>A p.L2319I (on ENST00000621958; = p.L2318I on NM_001004334.4) | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- GPR179 | c.4489G>T p.G1497W (on ENST00000621958; = p.G1496W on NM_001004334.4) | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GSE1 | c.365_366dup p.V123Pfs*3 | Frame Shift Ins (INS) | VAF 17/94 reads (18%) | called by mutect2, varscan2
- GXYLT1 | c.1225dup p.T409Nfs*70 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- HORMAD1 | c.848del p.N283Tfs*12 | Frame Shift Del (DEL) | VAF 9/21 reads (43%) | called by mutect2, varscan2
- HS2ST1 | c.335del p.N112Ifs*4 | Frame Shift Del (DEL) | VAF 11/112 reads (10%) | called by mutect2, pindel, varscan2
- IGHV3OR16-8 | c.339T>A p.Y113* | Nonsense Mutation (SNP) | VAF 68/230 reads (30%) | called by muse, mutect2, varscan2
- IL5RA | c.864del p.K288Nfs*2 | Frame Shift Del (DEL) | VAF 32/108 reads (30%) | called by mutect2, pindel, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | called by mutect2, pindel, varscan2
- KAT8 | c.1344del p.K449Sfs*20 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- KIF13A | c.845del p.L282Wfs*44 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- KMT2B | c.1656del p.K553Nfs*52 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- KMT2C | c.8445dup p.S2816Ifs*6 | Frame Shift Ins (INS) | VAF 37/123 reads (30%) | called by mutect2, pindel, varscan2
- KNG1 | c.1523dup p.N508Kfs*2 | Frame Shift Ins (INS) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- KNTC1 | c.4938del p.K1646Nfs*2 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, varscan2
- LRRC27 | c.93del p.S32Pfs*19 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- LRRC45 | c.566del p.G189Afs*5 | Frame Shift Del (DEL) | VAF 21/107 reads (20%) | called by mutect2, pindel, varscan2
- MAP7D1 | c.1440del p.C481Afs*94 | Frame Shift Del (DEL) | VAF 39/119 reads (33%) | called by mutect2, pindel, varscan2
- MCTP2 | c.1996del p.R666Efs*23 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by mutect2, pindel, varscan2
- MVP | c.35del p.P12Hfs*40 | Frame Shift Del (DEL) | VAF 25/123 reads (20%) | called by mutect2, pindel, varscan2
- N4BP2L2 | c.2384dup p.T796Hfs*6 (on ENST00000674422; = p.T367Hfs*6 on NM_033111.4) | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- NAA15 | c.798del p.A267Hfs*8 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- NEU4 | c.96dup p.G33Rfs*15 (on ENST00000391969 / NM_001167602.3; = p.G45Rfs*15 on NM_080741.4) | Frame Shift Ins (INS) | VAF 11/47 reads (23%) | called by mutect2, pindel
- NPHP4 | c.477del p.R160Efs*18 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- NR4A2 | c.325del p.Q109Sfs*5 | Frame Shift Del (DEL) | VAF 25/86 reads (29%) | called by mutect2, pindel, varscan2
- NSD3 | c.481_482del p.I161Pfs*8 | Frame Shift Del (DEL) | VAF 31/170 reads (18%) | called by mutect2, pindel, varscan2
- OTOF | c.5291+1del p.X1764_splice (on ENST00000272371 / NM_194248.3; = p.X997_splice on NM_004802.4) | Splice Site (DEL) | VAF 57/229 reads (25%) | called by mutect2, pindel, varscan2
- PADI4 | c.1797dup p.K600Qfs*113 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- PALM2AKAP2 | c.490del p.V164Sfs*15 (on ENST00000374531 / NM_001037293.2; = p.V196Sfs*15 on NM_053016.6) | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- PGBD1 | c.2285dup p.L762Ffs*7 | Frame Shift Ins (INS) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- PHACTR2 | c.1487del p.N496Tfs*22 | Frame Shift Del (DEL) | VAF 24/81 reads (30%) | called by mutect2, pindel, varscan2
- PIK3C3 | c.2260del p.T754Qfs*7 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.5495dup p.V1833Sfs*36 | Frame Shift Ins (INS) | VAF 13/79 reads (16%) | called by mutect2, pindel, varscan2
- PLB1 | c.889del p.R297Dfs*16 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- PNMA1 | c.831_832del p.K278Gfs*4 | Frame Shift Del (DEL) | VAF 19/81 reads (23%) | called by pindel, varscan2
- PPIAL4A | c.175G>T p.G59W | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R13L | c.342del p.K115Rfs*109 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- PPP4R2 | c.51del p.K19Rfs*14 | Frame Shift Del (DEL) | VAF 42/219 reads (19%) | called by mutect2, pindel, varscan2
- PRR3 | c.448del p.Q150Rfs*55 | Frame Shift Del (DEL) | VAF 43/161 reads (27%) | called by mutect2, pindel, varscan2
- PRSS33 | c.208del p.Q70Sfs*4 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by pindel, varscan2
- PRSS53 | c.680del p.P227Lfs*32 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- PTOV1 | c.1248del p.*417Sfs*14 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- PTPRT | c.1106del p.G369Vfs*28 | Frame Shift Del (DEL) | VAF 19/100 reads (19%) | called by mutect2, pindel, varscan2
- RASA2 | c.1967del p.N656Tfs*21 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- ROCK2 | c.4040del p.K1347Rfs*21 | Frame Shift Del (DEL) | VAF 88/313 reads (28%) | called by mutect2, pindel, varscan2
- SCARA5 | c.134C>G p.A45G | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SEMA4G | c.1910del p.N637Mfs*37 (on ENST00000370250; = p.N642Mfs*37 on NM_017893.3) | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- SETD2 | c.4219dup p.R1407Kfs*8 | Frame Shift Ins (INS) | VAF 11/38 reads (29%) | called by mutect2, varscan2
- SHISA4 | c.258del p.I86Mfs*8 | Frame Shift Del (DEL) | VAF 54/199 reads (27%) | called by mutect2, pindel, varscan2
- SHOX | c.418del p.H140Ifs*52 | Frame Shift Del (DEL) | VAF 7/14 reads (50%) | called by mutect2, varscan2
- SLC27A6 | c.1254del p.G419Efs*10 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- SLC39A7 | c.25del p.H9Tfs*8 | Frame Shift Del (DEL) | VAF 55/180 reads (31%) | called by mutect2, pindel, varscan2
- SLITRK1 | c.312dup p.L105Afs*34 | Frame Shift Ins (INS) | VAF 30/102 reads (29%) | called by mutect2, pindel, varscan2
- SLITRK6 | c.2055del p.M686Wfs*50 | Frame Shift Del (DEL) | VAF 76/281 reads (27%) | called by mutect2, pindel, varscan2
- SNCB | c.175dup p.T59Nfs*34 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- SPATA2 | c.916del p.H306Tfs*202 | Frame Shift Del (DEL) | VAF 42/132 reads (32%) | called by mutect2, pindel, varscan2
- SPG7 | c.1145del p.R382Lfs*50 (on ENST00000268704; = p.R389Lfs*50 on NM_003119.4) | Frame Shift Del (DEL) | VAF 54/166 reads (33%) | called by mutect2, pindel, varscan2
- SUPT6H | c.5130del p.M1711Cfs*51 | Frame Shift Del (DEL) | VAF 28/121 reads (23%) | called by mutect2, pindel, varscan2
- SYNGAP1 | c.3903del p.L1302Wfs*8 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- TATDN1 | c.882del p.P295Lfs*19 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel
- THG1L | c.850del p.D284Mfs*11 | Frame Shift Del (DEL) | VAF 41/136 reads (30%) | called by mutect2, pindel, varscan2
- TMEM132D | c.618del p.T207Rfs*75 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- TRIM9 | c.142del p.Q48Rfs*21 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- TRPM3 | c.1637del p.K546Sfs*24 (on ENST00000357533 / NM_001366142.2; = p.K391Rfs*12 on NM_020952.6) | Frame Shift Del (DEL) | VAF 27/77 reads (35%) | called by mutect2, pindel, varscan2
- TSHZ2 | c.1598del p.N533Tfs*43 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel, varscan2
- TTBK2 | c.2482del p.T828Hfs*16 | Frame Shift Del (DEL) | VAF 13/108 reads (12%) | called by mutect2, pindel, varscan2
- U2SURP | c.3015del p.K1005Nfs*30 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- UTRN | c.5603_5605del p.L1868del | In Frame Del (DEL) | VAF 30/138 reads (22%) | called by pindel, varscan2
- WAPL | c.1435del p.R479Efs*46 | Frame Shift Del (DEL) | VAF 32/96 reads (33%) | called by mutect2, pindel, varscan2
- WDR55 | c.1021_1022del p.K341Gfs*16 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- WRNIP1 | c.1839del p.V614Cfs*5 | Frame Shift Del (DEL) | VAF 22/89 reads (25%) | called by mutect2, pindel, varscan2
- XPO4 | c.2492del p.L831* | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- ZCCHC8 | c.104A>G p.D35G | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- ZFHX4 | c.7939dup p.R2647Kfs*29 | Frame Shift Ins (INS) | VAF 17/80 reads (21%) | called by mutect2, varscan2
- ZGLP1 | c.72del p.W25Gfs*107 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- ZNF214 | c.494del p.G165Afs*21 | Frame Shift Del (DEL) | VAF 37/148 reads (25%) | called by mutect2, pindel, varscan2
- ZNF518A | c.2784_2785del p.K928Nfs*18 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, varscan2
- ZNF579 | c.1055del p.G352Afs*53 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- AATK | c.180C>T p.I60= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs745405011, COSV58689026; called by muse, mutect2, varscan2
- ABCC10 | c.642T>C p.A214= (on ENST00000372530 / NM_001198934.2; = p.A171= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/164 reads (34%) | catalogued as rs141145411; called by muse, mutect2, varscan2
- ACSS1 | c.747G>A p.L249= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV60221399; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2229G>A p.T743= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs375944574; called by muse, mutect2, varscan2
- ADCY7 | c.1545C>T p.N515= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs144290211; called by muse, mutect2, varscan2
- ADGRL1 | c.138C>T p.I46= | Silent (SNP) | VAF 52/147 reads (35%) | catalogued as rs562415321, COSV61564234; called by muse, mutect2, varscan2
- AHNAK2 | c.10290T>C p.P3430= | Silent (SNP) | VAF 116/359 reads (32%) | catalogued as rs754645832, COSV60918575; called by muse, mutect2, varscan2
- AK5 | c.1047T>C p.D349= (on ENST00000354567 / NM_174858.3; = p.D323= on NM_012093.4) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV60974888; called by muse, mutect2, varscan2
- AMBN | c.954C>T p.N318= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs145240720; called by muse, mutect2, varscan2
- AMMECR1L | c.912C>A p.P304= | Silent (SNP) | VAF 35/151 reads (23%) | catalogued as COSV55761052; called by muse, mutect2, varscan2
- ANKRD17 | c.2520T>C p.A840= | Silent (SNP) | VAF 22/260 reads (8%) | catalogued as COSV58222491; called by muse, mutect2
- ARHGEF40 | c.1438C>T p.L480= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV53881202; called by muse, mutect2, varscan2
- ARSB | c.88C>T p.L30= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs766870239, COSV53723581; ClinVar: likely benign; called by muse, mutect2, varscan2
- ASPM | c.1824G>A p.E608= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as COSV54132008; called by muse, mutect2, varscan2
- ATG4C | c.963T>C p.G321= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV58603463; called by muse, mutect2
- BCAS3 | c.2256A>G p.S752= (on ENST00000390652 / NM_001353144.2; = p.S737= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV66775899; called by muse, mutect2, varscan2
- BRINP1 | c.645C>T p.S215= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs373900703; called by muse, mutect2, varscan2
- BTBD9 | c.769C>A p.R257= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as COSV58424985, COSV58428560; called by muse, varscan2
- CCNQ | c.366G>C p.V122= | Silent (SNP) | VAF 32/53 reads (60%) | catalogued as COSV52344672; called by muse, mutect2, varscan2
- CDX1 | c.48C>G p.G16= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV51568621; called by muse, mutect2
- CFAP298 | c.192A>G p.G64= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV51592489; called by muse, mutect2, varscan2
- CHD8 | c.2604G>A p.L868= (on ENST00000646647 / NM_001170629.2; = p.L589= on NM_020920.4) | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as rs1435393389, COSV67869955; called by muse, mutect2, varscan2
- CLSTN1 | c.1005C>T p.A335= (on ENST00000377298 / NM_001009566.3; = p.A325= on NM_014944.4) | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs757962287, COSV63648724; called by muse, mutect2, varscan2
- CLSTN2 | c.270G>T p.L90= | Silent (SNP) | VAF 62/212 reads (29%) | catalogued as COSV71721546; called by muse, mutect2, varscan2
- CNTNAP2 | c.1635G>A p.A545= | Silent (SNP) | VAF 45/163 reads (28%) | catalogued as rs755959345, COSV62180843, COSV62199646; called by muse, mutect2, varscan2
- COL5A1 | c.3054G>A p.G1018= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs369163868, COSV65670359; ClinVar: likely benign; called by muse, mutect2, varscan2
- COQ5 | c.390C>T p.S130= | Silent (SNP) | VAF 63/216 reads (29%) | catalogued as COSV56019396; called by muse, mutect2, varscan2
- CSGALNACT1 | c.594C>T p.S198= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV59979103; called by muse, mutect2, varscan2
- CSMD3 | c.7224G>A p.T2408= (on ENST00000297405 / NM_001363185.1; = p.T2304= on NM_052900.3) | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as rs781779613, COSV52212247, COSV52298395; called by muse, mutect2, varscan2
- DDOST | c.72C>T p.A24= (on ENST00000415136; = p.A7= on NM_005216.5) | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1031513510, COSV56119300; called by muse, mutect2, varscan2
- DDX4 | c.1944G>A p.S648= | Silent (SNP) | VAF 57/155 reads (37%) | catalogued as rs1038782503, COSV61755534; called by muse, mutect2, varscan2
- DISP2 | c.1002C>T p.C334= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs1003191504, COSV51125603; called by muse, mutect2, varscan2
- DLG5 | c.2649C>A p.A883= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100967464; called by muse, mutect2, varscan2
- DNAJB14 | c.210C>T p.G70= | Silent (SNP) | VAF 69/201 reads (34%) | catalogued as rs760666436, COSV62033366; called by muse, mutect2, varscan2
- DOCK2 | c.723C>T p.F241= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV56943247; called by muse, mutect2, varscan2
- DSG2 | c.516T>C p.S172= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV55200076; called by muse, mutect2, varscan2
- DUOX2 | c.1336C>T p.L446= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV66532700; called by muse, mutect2, varscan2
- ELAPOR1 | c.1797C>A p.G599= | Silent (SNP) | VAF 112/371 reads (30%) | catalogued as COSV64040623; called by muse, mutect2, varscan2
- ESRRB | c.243C>T p.S81= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs371102435; called by muse, mutect2, varscan2
- EVX2 | c.861C>T p.Y287= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs369068866; called by muse, mutect2
- FAM110B | c.168C>T p.A56= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs775487158, COSV64066003; called by muse, mutect2, varscan2
- FAM135B | c.36A>G p.V12= | Silent (SNP) | VAF 51/172 reads (30%) | catalogued as COSV50528503; called by muse, mutect2, varscan2
- FER1L6 | c.3222T>C p.S1074= | Silent (SNP) | VAF 45/201 reads (22%) | catalogued as rs764442627, COSV101206203, COSV67550736; called by muse, mutect2, varscan2
- FES | c.1179C>T p.P393= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs201149672; called by muse, mutect2, varscan2
- FLG | c.11022A>G p.S3674= | Silent (SNP) | VAF 90/471 reads (19%) | catalogued as rs1373411288, COSV100911554; called by muse, mutect2, varscan2
- FOXA1 | c.795C>A p.R265= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV51646773; called by muse, mutect2
- FOXD4L4 | c.861C>T p.G287= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as rs1409197339; called by muse, mutect2, varscan2
- FOXD4L6 | c.861C>T p.G287= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1268088110; called by mutect2, varscan2
- GNA11 | c.195C>T p.A65= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs576887084, COSV50020412; ClinVar: likely benign; called by muse, mutect2, varscan2
- GNAS | c.474A>G p.G158= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV55678961, COSV55679195; called by muse, mutect2
- GNAT1 | c.639C>T p.G213= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV51697720; called by muse, mutect2, varscan2
- GNPTG | c.687G>A p.Q229= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV50190248; called by muse, mutect2, varscan2
- GRB7 | c.57A>G p.P19= | Silent (SNP) | VAF 83/215 reads (39%) | catalogued as rs778062709, COSV58448669; called by muse, mutect2, varscan2
- GRIA4 | c.2418G>A p.T806= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as rs571198495, COSV56902794; called by muse, mutect2
- GRIN2A | c.1629C>T p.T543= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as rs758378272, COSV100409723, COSV58019096; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- GTPBP6 | c.1545A>G p.P515= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100397731; called by muse, mutect2
- HBS1L | c.1641C>T p.G547= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as rs1291615810, COSV63201625; called by muse, mutect2
- HECTD1 | c.5169G>A p.T1723= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as rs1170577960, COSV67944922; called by muse, mutect2, varscan2
- HPGD | c.462A>G p.S154= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV56663071; called by muse, mutect2, varscan2
- HSPA4L | c.966A>G p.K322= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV56546216, COSV56548979; called by muse, mutect2, varscan2
- HSPG2 | c.8544C>T p.C2848= | Silent (SNP) | VAF 43/128 reads (34%) | catalogued as rs369778477; called by muse, mutect2, varscan2
- IFNGR1 | c.1053T>C p.S351= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV62992179; called by muse, mutect2
- IGHV3-13 | c.84A>G p.G28= | Silent (SNP) | VAF 53/174 reads (30%) | called by muse, mutect2, varscan2
- IGHV3-74 | c.237C>T p.Y79= | Silent (SNP) | VAF 57/188 reads (30%) | catalogued as rs761799364; called by muse, mutect2, varscan2
- IGSF10 | c.117G>A p.T39= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs755271534, COSV56786850; called by muse, mutect2, varscan2
- IL12RB2 | c.1509A>G p.S503= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as rs771180528, COSV52024104; called by muse, mutect2, varscan2
- IL6R | c.924G>A p.P308= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs1234709208, COSV59817161; called by muse, mutect2, varscan2
- INMT | c.531C>T p.R177= | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as rs768940876, COSV50001594; called by muse, mutect2, varscan2
- JAG2 | c.1173G>A p.S391= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1194152666, COSV59307536; called by muse, mutect2, varscan2
- KCNB2 | c.360C>T p.G120= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV73050918; called by muse, mutect2, varscan2
- KMT5A | c.234T>C p.H78= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV100389551, COSV57863557; called by muse, mutect2, varscan2
- KYNU | c.1302A>G p.R434= | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as rs1032476416, COSV51585480; called by muse, mutect2, varscan2
- LRP11 | c.837C>T p.T279= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as rs1278470316, COSV53334249; called by muse, mutect2
- LRRC41 | c.150C>T p.C50= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV58440496; called by muse, mutect2
- LRRC8D | c.756A>G p.P252= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV61579781; called by muse, mutect2, varscan2
- MAST1 | c.2334G>A p.A778= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV52248695; called by muse, mutect2
- MBD6 | c.927G>A p.T309= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs368099392; called by muse, mutect2, varscan2
- MORF4L1 | c.894A>G p.G298= (on ENST00000331268 / NM_206839.2; = p.G259= on NM_006791.4) | Silent (SNP) | VAF 46/162 reads (28%) | catalogued as COSV58704724; called by muse, mutect2, varscan2
- MPG | c.102G>A p.S34= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as rs754765496, COSV54738703; called by muse, mutect2, varscan2
- MSH3 | c.2172C>T p.D724= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs541680738, COSV54154346; called by muse, mutect2, varscan2
- MSLN | c.714G>A p.S238= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs774690027, COSV53500695; called by muse, mutect2, varscan2
- MYO18B | c.6099C>T p.A2033= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs369440760; called by muse, mutect2, varscan2
- MYOC | c.831C>T p.T277= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV50675625; called by muse, mutect2, varscan2
- MYOM2 | c.1389G>A p.A463= | Silent (SNP) | VAF 93/440 reads (21%) | catalogued as rs776329823, COSV50705177, COSV50743116; called by muse, mutect2, varscan2
- NAPSA | c.972C>T p.P324= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as rs372982608; called by muse, mutect2, varscan2
- NCOA2 | c.2658T>C p.N886= | Silent (SNP) | VAF 43/154 reads (28%) | catalogued as COSV51218601; called by muse, mutect2, varscan2
- NFASC | c.1728C>A p.S576= (on ENST00000339876 / NM_001378329.1; = p.S587= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/260 reads (30%) | catalogued as COSV58368754; called by muse, mutect2, varscan2
- NINL | c.1399A>C p.R467= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as COSV54004070; called by muse, mutect2, varscan2
- NKX2-1 | c.177G>A p.G59= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1231790904, CD1414462, COSV61389095; called by muse, mutect2, varscan2
- NLGN4Y | c.99C>A p.A33= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV52970334; called by muse, mutect2, varscan2
- NLRP6 | c.1233G>A p.T411= | Silent (SNP) | VAF 113/269 reads (42%) | catalogued as COSV56460335; called by muse, mutect2, varscan2
- NPDC1 | c.348G>A p.P116= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs755313806, COSV58664541; called by muse, mutect2, varscan2
- NPHS1 | c.855G>A p.V285= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs775775612, COSV62288472; called by muse, mutect2, varscan2
- NPTN | c.342C>T p.Y114= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs1209826522, COSV54737795; called by muse, mutect2, varscan2
- NT5E | c.1047C>A p.S349= | Silent (SNP) | VAF 51/173 reads (29%) | catalogued as COSV57628873; called by muse, mutect2, varscan2
- ODF4 | c.285A>T p.L95= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV60272285; called by muse, mutect2
- ONECUT2 | c.711C>T p.G237= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs577405693, COSV72203215; called by muse, mutect2, varscan2
- OR56A3 | c.393C>T p.C131= | Silent (SNP) | VAF 49/160 reads (31%) | catalogued as COSV61568834; called by muse, mutect2, varscan2
- OR8I2 | c.603A>G p.L201= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as COSV56168518; called by muse, mutect2
- OTUD6A | c.837C>T p.A279= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs766943755, COSV57973703; called by muse, mutect2, varscan2
- PAGE2 | c.33C>A p.S11= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100892298; called by muse, mutect2
- PALD1 | c.1314T>C p.L438= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV54974856; called by muse, mutect2, varscan2
- PAPSS2 | c.927G>A p.R309= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as COSV63263735; called by muse, mutect2, varscan2
- PCDHB1 | c.348C>A p.S116= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV60631563; called by muse, mutect2, varscan2
- PCDHB7 | c.714C>T p.N238= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as rs782421028, COSV50760211; called by muse, mutect2, varscan2
- PCDHGA9 | c.309G>A p.L103= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV53968080; called by muse, mutect2, varscan2
- PDHA1 | c.894A>C p.G298= | Silent (SNP) | VAF 61/92 reads (66%) | catalogued as COSV58832206; called by muse, mutect2, varscan2
- PDZRN4 | c.273G>A p.S91= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs757152985, COSV101284559; called by muse, varscan2
- PHF21B | c.504C>T p.A168= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs749264266, COSV57559223; called by muse, mutect2, varscan2
- PHOX2B | c.492G>A p.A164= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs761776635, COSV56930104, COSV99891323; called by muse, mutect2, varscan2
- PLCB3 | c.2481C>T p.N827= | Silent (SNP) | VAF 62/208 reads (30%) | catalogued as rs377311495; called by muse, mutect2, varscan2
- PLEKHF1 | c.54G>T p.V18= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV71410160; called by muse, mutect2, varscan2
- PPA2 | c.432C>G p.T144= | Silent (SNP) | VAF 24/138 reads (17%) | catalogued as COSV58996257; called by muse, varscan2
- PPP1R13L | c.1704C>A p.P568= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as COSV62908821; called by muse, mutect2, varscan2
- PRAM1 | c.1593T>C p.V531= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV55314375; called by muse, mutect2, varscan2
- PTGDR2 | c.594G>A p.T198= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV57124985; called by muse, mutect2, varscan2
- RASA3 | c.1962G>A p.A654= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as rs761708403, COSV61868584; called by muse, mutect2, varscan2
- RASEF | c.663G>A p.R221= | Silent (SNP) | VAF 46/147 reads (31%) | catalogued as COSV64587544; called by muse, mutect2, varscan2
- REC8 | c.900C>T p.R300= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV61015271; called by muse, varscan2
- RHBDF2 | c.1032C>T p.V344= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as COSV57421084; called by muse, mutect2, varscan2
- RIOK3 | c.1008C>T p.L336= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs766327455, COSV59773593; called by muse, mutect2
- RSBN1 | c.678G>A p.V226= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV54731082; called by muse, mutect2, varscan2
- SLC16A3 | c.882C>T p.S294= | Silent (SNP) | VAF 47/158 reads (30%) | catalogued as rs571273730, COSV66429057; called by muse, mutect2, varscan2
- SLC6A3 | c.615C>T p.N205= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs764540812, COSV54362848; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMAD5 | c.516G>A p.T172= | Silent (SNP) | VAF 106/319 reads (33%) | catalogued as rs371132923; called by muse, mutect2, varscan2
- SNAP91 | c.2643C>T p.S881= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1353144709, COSV52125156; called by muse, mutect2, varscan2
- SNCB | c.42C>T p.G14= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs373426715; called by muse, varscan2
- SON | c.3478T>C p.L1160= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV51661652; called by muse, mutect2, varscan2
- SPART | c.705T>A p.P235= | Silent (SNP) | VAF 5/89 reads (6%) | catalogued as COSV100768726; called by muse, mutect2
- SPINDOC | c.1110T>C p.T370= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV53692881; called by muse, mutect2, varscan2
- SPON1 | c.75G>A p.A25= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV59962583; called by muse, mutect2, varscan2
49 further variants in this file (0 protein-altering or splice-affecting, 31 silent, 18 other) are not listed here.
